Somatic mutation profile of tumor specimen TARGET-10-PASPBU-09A (aliquot TARGET-10-PASPBU-09A-01D) from TARGET case TARGET-10-PASPBU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,673 days).
Specimen TARGET-10-PASPBU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f63d5147-d8eb-4ff3-819b-408a8ce871eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASPBU-10A (Blood Derived Normal), aliquot TARGET-10-PASPBU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65c43daf-0a80-444a-8b96-cb1a7d3292a6

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Intron 4, Splice Region 1, Frame Shift Ins 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2
- C16orf96 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs74005360; called by muse, mutect2, varscan2
- DACH2 | c.953T>A p.M318K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV64160915; called by muse, mutect2, varscan2
- EDNRA | c.-68G>T | Splice Region (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100163576; called by muse, mutect2, varscan2
- EFCAB5 | c.2104T>C p.S702P | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV57925464; called by muse, mutect2, varscan2
- EXOC2 | c.142T>C p.C48R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57860771; called by muse, mutect2, varscan2
- NDST1 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484836650, COSV55784704, COSV55786084; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, varscan2
- RGMA | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs752421802, COSV61232765; called by muse, mutect2, varscan2
- RTN3 | c.3089dup p.A1031Gfs*28 (on ENST00000377819 / NM_001265589.2; = p.A235Gfs*28 on NM_006054.4) | Frame Shift Ins (INS) | VAF 30/66 reads (45%) | catalogued as rs747510098; called by mutect2, varscan2
- SLCO4C1 | c.2078C>A p.P693H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60512402; called by muse, mutect2, varscan2
- STX18 | c.897C>G p.N299K | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100086499, COSV60371368; called by muse, mutect2, varscan2
- SULT1E1 | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56945946, COSV56947537; called by muse, mutect2, varscan2
- ADAMTSL2 | c.755A>T p.D252V | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGHV3-43 | chr14:106470263 TATC>AGGCACAGGA | Missense Mutation (INS) | VAF 38/87 reads (44%) | called by pindel, varscan2*
- PALLD | c.2194A>T p.N732Y | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2
- PER2 | c.1907A>T p.E636V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- CARF | c.1431T>C p.H477= | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- COL21A1 | c.561G>A p.S187= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs376475214, COSV104391867; called by muse, mutect2
- GFM1 | c.1503G>T p.L501= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1418751403; called by muse, mutect2, varscan2
- GGT6 | c.1020G>A p.P340= (on ENST00000574154 / NM_001122890.3; = p.P308= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs755584588, COSV99626471; called by muse, mutect2
- AQP6 | c.*1456G>T | 3'UTR (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- EIF2AK4 | c.4303-11G>A | Intron (SNP) | VAF 14/116 reads (12%) | catalogued as rs1258182631; called by muse, mutect2, varscan2
- MEFV | c.1357-69G>A | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- MUC19 | n.5076C>T | RNA (SNP) | VAF 19/82 reads (23%) | catalogued as rs574471902; called by muse, mutect2, varscan2
- POLR1G | c.23-94T>A | Intron (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- ZNF252P | n.245+4223A>G | Intron (SNP) | VAF 18/199 reads (9%) | called by muse, mutect2
